Somatic mutation profile of tumor specimen TCGA-DD-AACF-01A (aliquot TCGA-DD-AACF-01A-11D-A40R-10) from TCGA case TCGA-DD-AACF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.9 years (25,172 days).
Specimen TCGA-DD-AACF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ee69b0b-f78d-4a20-8321-73f40bc3b668.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACF-10A (Blood Derived Normal), aliquot TCGA-DD-AACF-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9927bcbb-1ae1-46f1-9d4b-720d439e6586

The open-access MAF lists 139 somatic variants for this specimen: 107 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 31, Frame Shift Del 9, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK1 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853203, CM970075, COSV99802350; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AIFM1 | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 174/193 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99780902; called by muse, mutect2, varscan2
- ANAPC7 | c.1741G>A p.G581S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV101482849; called by muse, mutect2, varscan2
- ANKFY1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100492456; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1179A>T p.E393D | Missense Mutation (SNP) | VAF 185/649 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs887291683, COSV99782688; called by muse, mutect2, varscan2
- ANKRD13A | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55678052, COSV99923874; called by muse, mutect2, varscan2
- ATP6V1H | c.1190T>G p.L397R | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100778623; called by muse, mutect2, varscan2
- ATP8B2 | c.1939C>T p.R647* (on ENST00000672630; = p.R614* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/277 reads (3%) | catalogued as rs1263937344, COSV100527831; called by muse, mutect2
- ATR | c.6366A>G p.I2122M | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as COSV100637906; called by muse, mutect2, varscan2
- BAX | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.65); catalogued as rs369660551; called by muse, mutect2, varscan2
- BCLAF1 | c.755A>C p.H252P | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs1478646288, COSV100786523; called by muse, mutect2, varscan2
- BEST2 | c.248-2A>G p.X83_splice | Splice Site (SNP) | VAF 28/62 reads (45%) | catalogued as COSV99244322; called by muse, mutect2, varscan2
- BIRC6 | c.6365C>G p.S2122C | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428048; called by muse, mutect2, varscan2
- C14orf93 | c.1003T>G p.S335A | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.104); catalogued as COSV100136651; called by muse, mutect2, varscan2
- C8orf33 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1269844120, COSV100510494; called by muse, mutect2, varscan2
- CADPS2 | c.2509C>A p.L837M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1227026317, COSV100461742; called by muse, mutect2, varscan2
- CALHM2 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777105138, COSV99588372; called by muse, mutect2, varscan2
- CCDC39 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.409); catalogued as COSV99868025; called by muse, mutect2, varscan2
- CD207 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs975768838, COSV101338539; called by muse, mutect2, varscan2
- CEP350 | c.4579G>T p.D1527Y | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100854424; called by muse, mutect2, varscan2
- CHRM1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1213211267, COSV100186134; called by muse, mutect2, varscan2
- CHST7 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV99332865; called by muse, mutect2, varscan2
- CHSY1 | c.1539G>C p.K513N | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0.21); catalogued as COSV99573756; called by muse, mutect2, varscan2
- CLCA1 | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99322100; called by muse, mutect2, varscan2
- COL7A1 | c.5657A>T p.Q1886L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.945); catalogued as CD993040, COSV100095531; called by muse, mutect2, varscan2
- CPXM1 | c.1860+1G>A p.X620_splice | Splice Site (SNP) | VAF 44/94 reads (47%) | catalogued as COSV101013699; called by muse, mutect2, varscan2
- CR2 | c.1232A>G p.Q411R | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1328106132, COSV100889568; called by muse, mutect2, varscan2
- CRYBG1 | c.5095G>A p.G1699R | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100954428; called by muse, mutect2, varscan2
- CTDSP1 | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99811913; called by muse, mutect2, varscan2
- CYBA | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99879827; called by muse, mutect2, varscan2
- DENND4A | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.968); catalogued as COSV101475290; called by muse, mutect2, varscan2
- DGKA | c.1879C>G p.Q627E | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.102); catalogued as COSV100092839; called by muse, mutect2, varscan2
- DIAPH3 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99933100; called by muse, mutect2, varscan2
- DNAJC27 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 119/280 reads (43%) | catalogued as rs147784881; called by muse, mutect2, varscan2
- ECE1 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV51670351; called by muse, mutect2, varscan2
- GPATCH2 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 183/745 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs895220342, COSV100861642; called by muse, mutect2, varscan2
- GREM2 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV100547399; called by muse, mutect2, varscan2
- GRM4 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774098056, COSV65215613, COSV65218143; called by muse, mutect2, varscan2
- GSTM3 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99860180; called by muse, mutect2, varscan2
- IFNA14 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101207307; called by muse, mutect2, varscan2
- IL1RAPL2 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 198/416 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.334); catalogued as COSV100781003; called by muse, varscan2
- INPP4B | c.1652G>C p.G551A | Missense Mutation (SNP) | VAF 77/103 reads (75%) | SIFT tolerated (0.6); PolyPhen benign (0.197); catalogued as COSV99523682; called by muse, mutect2, varscan2
- INTS8 | c.2359A>G p.I787V | Missense Mutation (SNP) | VAF 377/590 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs778617408, COSV100569202; called by muse, mutect2, varscan2
- KANSL1L | c.2624T>G p.F875C | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.326); catalogued as COSV99910334; called by muse, mutect2, varscan2
- KMT2D | c.11695C>T p.Q3899* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV56444849, COSV99979179; called by muse, mutect2, varscan2
- LGR5 | c.1636+2T>G p.X546_splice | Splice Site (SNP) | VAF 57/107 reads (53%) | catalogued as COSV99877740; called by muse, mutect2, varscan2
- LIPE | c.2260C>G p.P754A | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV99733964; called by muse, mutect2, varscan2
- LRIG1 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV56239064; called by muse, mutect2, varscan2
- LRP1B | c.1066A>T p.M356L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101254688; called by muse, mutect2, varscan2
- MAGEF1 | c.56A>G p.K19R | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.97); PolyPhen benign (0.027); catalogued as COSV100510933; called by muse, mutect2, varscan2
- MAN2C1 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs759137835, COSV99145293; called by muse, mutect2, varscan2
- MARCO | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100503329; called by muse, mutect2, varscan2
- MGRN1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780003440, COSV52151113; called by muse, mutect2, varscan2
- MICAL3 | c.1734T>A p.N578K | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99260722; called by muse, mutect2, varscan2
- MMS22L | c.3093T>G p.I1031M | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as COSV99246407; called by muse, mutect2, varscan2
- MUC17 | c.7046T>C p.M2349T | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1235271194, COSV100072474; called by muse, mutect2, varscan2
- MYO10 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV101569775; called by muse, mutect2, varscan2
- MZT2A | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100520830, COSV58760223; called by muse, mutect2, varscan2
- NCOA3 | c.1443G>T p.M481I | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs753792930, COSV100507351; called by muse, mutect2, varscan2
- NCOR2 | c.3400C>T p.H1134Y | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV100657087; called by muse, mutect2, varscan2
- NMUR2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs756384094, COSV54918385; called by muse, mutect2, varscan2
- NUP58 | c.930A>T p.K310N | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV101098655; called by muse, mutect2, varscan2
- OR1N1 | c.827A>C p.Y276S | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509690; called by muse, mutect2, varscan2
- OR5L1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753420191, COSV61733834; called by muse, mutect2
- OR6C2 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV100498671; called by muse, mutect2, varscan2
- P2RY14 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99852232; called by muse, mutect2, varscan2
- PARP16 | c.318A>T p.E106D | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV99975368; called by muse, mutect2, varscan2
- PCDH17 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.808); catalogued as COSV64976982, COSV64979535; called by muse, mutect2, varscan2
- PCNT | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV100855255; called by muse, mutect2, varscan2
- PDGFRA | c.3002A>T p.K1001M | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99956134; called by muse, mutect2, varscan2
- PDGFRA | c.3003G>T p.K1001N | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV57266499, COSV57271932; called by muse, mutect2, varscan2
- PRELP | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479398727, COSV100557792; called by muse, mutect2, varscan2
- PRKAA1 | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 121/201 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV99713170; called by muse, mutect2, varscan2
- RPS27 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99667600; called by muse, mutect2, varscan2
- RSF1 | c.2665G>T p.D889Y | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100407028; called by muse, mutect2, varscan2
- RTN4 | c.3386C>T p.T1129I (on ENST00000337526 / NM_020532.5; = p.T136I on NM_007008.3) | Missense Mutation (SNP) | VAF 144/337 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100462897; called by muse, mutect2, varscan2
- SCAMP3 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as COSV100226642; called by muse, mutect2, varscan2
- SIPA1L2 | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 152/335 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477656; called by muse, mutect2, varscan2
- SIRT2 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99979304; called by muse, mutect2, varscan2
- SLC40A1 | c.986C>A p.T329K | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99656204; called by muse, mutect2, varscan2
- SPATA31D1 | c.1265G>T p.R422M | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368407426; called by muse, mutect2, varscan2
- TKFC | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99582335; called by muse, mutect2, varscan2
- TMTC2 | c.659A>C p.K220T | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV100337710; called by muse, mutect2, varscan2
- TTN | c.45131A>G p.N15044S (on ENST00000591111; = p.N7620S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | PolyPhen benign (0.443); catalogued as COSV100602518; called by muse, mutect2, varscan2
- UNC13A | c.3778C>A p.Q1260K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV53188081; called by muse, mutect2, varscan2
- UNC13C | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99514205; called by muse, mutect2, varscan2
- VPS13B | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 161/541 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100661422; called by muse, mutect2, varscan2
- ZFC3H1 | c.4592A>G p.H1531R | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101110422; called by muse, mutect2, varscan2
- ZFC3H1 | c.4591C>T p.H1531Y | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101110423; called by muse, mutect2, varscan2
- ZMYM3 | c.1630C>G p.R544G | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.43); catalogued as COSV100077654; called by muse, mutect2, varscan2
- ZNF746 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.838); catalogued as rs1358694651, COSV100502402; called by muse, mutect2, varscan2
- ZNF875 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV100183187; called by muse, mutect2, varscan2
- ZNF875 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as rs767652525, COSV60994473; called by muse, mutect2, varscan2
- ZNRF3 | c.524C>A p.P175Q (on ENST00000544604 / NM_001206998.2; = p.P75Q on NM_032173.3) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100238052; called by muse, mutect2, varscan2
- ZSWIM8 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101289852; called by muse, mutect2, varscan2
- DMXL2 | c.6957del p.W2319Cfs*4 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- FAM151A | c.163_167del p.Y55Afs*40 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- FOXD4L5 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by mutect2, varscan2
- HNRNPUL2 | c.1861_1877del p.I621Gfs*24 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by pindel, varscan2
- IFIT3 | c.110_130del p.R37_F44delinsI | In Frame Del (DEL) | VAF 49/209 reads (23%) | called by mutect2, pindel, varscan2
- KRIT1 | c.481del p.D161Ifs*4 | Frame Shift Del (DEL) | VAF 47/143 reads (33%) | called by mutect2, pindel, varscan2
- LAMB1 | c.3800_3844del p.V1267_T1281del | In Frame Del (DEL) | VAF 26/162 reads (16%) | called by mutect2, pindel
- LTBR | c.170del p.I57Tfs*39 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- NIPA2 | c.561_562del p.I188Rfs*46 | Frame Shift Del (DEL) | VAF 74/122 reads (61%) | called by mutect2, pindel, varscan2
- TP53 | c.426_453del p.V143Rfs*18 | Frame Shift Del (DEL) | VAF 34/60 reads (57%) | called by mutect2, pindel, varscan2
- UBAC1 | c.1107del p.F369Lfs*9 | Frame Shift Del (DEL) | VAF 41/102 reads (40%) | called by mutect2, pindel, varscan2
- YES1 | c.765_766del p.P256Nfs*26 | Frame Shift Del (DEL) | VAF 65/128 reads (51%) | called by mutect2, pindel, varscan2
- ADGRG7 | c.2133A>G p.T711= | Silent (SNP) | VAF 65/182 reads (36%) | catalogued as rs780285584, COSV99840764; called by muse, mutect2, varscan2
- AIF1L | c.207G>T p.L69= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV99908119; called by muse, mutect2, varscan2
- CELSR3 | c.7350C>T p.H2450= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as rs375748006; called by muse, mutect2, varscan2
- FBN3 | c.1962C>T p.P654= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV99560406; called by muse, mutect2
- FCHO1 | c.744A>G p.L248= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV99405949; called by muse, mutect2, varscan2
- HIF3A | c.1561C>A p.R521= (on ENST00000377670 / NM_152795.4; = p.R452= on NM_022462.4) | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as COSV99355648; called by muse, varscan2
- IFNA14 | c.423G>C p.L141= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV101207308; called by muse, mutect2, varscan2
- KIF15 | c.2868A>G p.V956= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV100392682; called by muse, mutect2, varscan2
- KLK4 | c.306C>A p.S102= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100133585, COSV60676125; called by muse, mutect2, varscan2
- LAMA5 | c.5802C>T p.R1934= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as COSV99438898; called by muse, mutect2, varscan2
- MUC16 | c.8646T>A p.T2882= | Silent (SNP) | VAF 91/201 reads (45%) | catalogued as COSV101199104; called by muse, mutect2, varscan2
- MVP | c.2607G>T p.G869= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV100651535; called by muse, mutect2, varscan2
- MYH4 | c.5076C>A p.L1692= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV99700709; called by muse, mutect2, varscan2
- MYH4 | c.1245C>A p.T415= | Silent (SNP) | VAF 66/164 reads (40%) | catalogued as rs1216880885, COSV99700710; called by muse, mutect2, varscan2
- MYO10 | c.1122C>A p.T374= | Silent (SNP) | VAF 55/192 reads (29%) | catalogued as COSV101569776; called by muse, mutect2, varscan2
- NBEAL1 | c.7968T>C p.V2656= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as COSV101355434; called by muse, mutect2, varscan2
- NFRKB | c.765T>C p.S255= (on ENST00000446488 / NM_001143835.2; = p.S280= on NM_006165.3) | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV100451841; called by muse, mutect2, varscan2
- NKAIN3 | c.45G>T p.A15= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100132715; called by muse, mutect2, varscan2
- NUP214 | c.5070T>G p.T1690= | Silent (SNP) | VAF 112/220 reads (51%) | catalogued as rs748199295, COSV100845204; called by muse, mutect2, varscan2
- OR4N2 | c.438G>A p.L146= | Silent (SNP) | VAF 104/218 reads (48%) | catalogued as COSV100269498; called by muse, varscan2
- PCDHAC1 | c.1806G>A p.R602= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as COSV99165448; called by muse, mutect2, varscan2
- PLXND1 | c.3798G>A p.G1266= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100139345; called by muse, mutect2, varscan2
- PRR30 | c.660G>T p.G220= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as COSV99574382; called by muse, mutect2, varscan2
- RABGGTA | c.930C>T p.N310= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as rs370715682; called by muse, mutect2, varscan2
- RADIL | c.2949C>A p.P983= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV101271323; called by muse, mutect2, varscan2
- REM2 | c.705C>T p.R235= | Silent (SNP) | VAF 15/265 reads (6%) | catalogued as COSV99944622; called by muse, mutect2
- RRM1 | c.1566A>G p.A522= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV100331262; called by muse, mutect2, varscan2
- SAMD14 | c.279G>T p.P93= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV99557391; called by muse, mutect2, varscan2
- TCHH | c.39A>G p.E13= | Silent (SNP) | VAF 56/139 reads (40%) | catalogued as rs1234821651, COSV100914948; called by muse, mutect2, varscan2
- TMEM150A | c.162C>G p.P54= (on ENST00000334462 / NM_001031738.3; = p.P24R on NM_153342.3) | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV100110494; called by muse, mutect2, varscan2
- TRPV3 | c.2373G>A p.*791= | Silent (SNP) | VAF 39/48 reads (81%) | catalogued as COSV100027596; called by muse, mutect2, varscan2
- MCF2L2 | c.*2C>G | 3'UTR (SNP) | VAF 34/101 reads (34%) | catalogued as COSV100191872; called by muse, mutect2, varscan2
